Somatic mutation profile of tumor specimen TCGA-DJ-A3UN-01A (aliquot TCGA-DJ-A3UN-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 51.7 years (18,871 days).
Specimen TCGA-DJ-A3UN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc6cce47-4a98-4831-85ae-deeee20a7bc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UN-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UN-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/358a7038-8209-4a34-97ed-2428b272d9fd

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TWIST1 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as rs104894058, CM990110, COSV54250217, COSV54251310; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADRA1A | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52357284; called by muse, mutect2, varscan2
- CNOT7 | c.588G>C p.K196N | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63517518; called by muse, mutect2, varscan2
- GFPT1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61946637; called by muse, mutect2, varscan2
- GRIN2D | c.1253G>C p.R418P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54377143; called by muse, mutect2, varscan2
- MBIP | c.106T>G p.S36A | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV59253251; called by muse, mutect2, varscan2
- PITPNM1 | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV62707438; called by muse, mutect2, varscan2
- TK1 | c.249C>A p.D83E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV56958833; called by muse, mutect2, varscan2
- WDR33 | c.3629C>G p.S1210C | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100460487, COSV59246357, COSV59248152; called by muse, mutect2, varscan2
- YWHAE | c.470A>T p.D157V | Missense Mutation (SNP) | VAF 11/331 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.022); catalogued as COSV51980702; called by muse, mutect2
- MX2 | c.159del p.K54Rfs*15 | Frame Shift Del (DEL) | VAF 74/242 reads (31%) | called by mutect2, pindel, varscan2
- CSMD2 | c.10248G>T p.L3416= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV53882719; called by muse, mutect2, varscan2
- SUPT6H | c.4368C>T p.T1456= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs767781917, COSV58924763; called by muse, mutect2, varscan2
